Somatic mutation profile of tumor specimen TARGET-10-PARBGG-09A (aliquot TARGET-10-PARBGG-09A-01D) from TARGET case TARGET-10-PARBGG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (685 days).
Specimen TARGET-10-PARBGG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a11adb0-6e4c-4bfa-adaf-f4b986f6b9e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBGG-10A (Blood Derived Normal), aliquot TARGET-10-PARBGG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f03ef1-b8be-4592-85bc-d47d25414f65

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSAD | c.713C>T p.P238L (on ENST00000444623 / NM_001244705.2; = p.P265L on NM_015989.5) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248041143, COSV57245666; called by muse, mutect2, varscan2
- IKZF1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441542459, COSV58782063; called by muse, varscan2
- IL12RB1 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs373257834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAX5 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63908478, COSV63914837; called by muse, mutect2, varscan2
- SLC4A5 | c.3046C>T p.R1016W | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767939908, COSV61026264; called by muse, mutect2, varscan2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PCP4 | c.*76C>T | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- TM9SF4 | c.229+760C>T | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as rs1422638839; called by muse, mutect2, varscan2
